Somatic mutation profile of tumor specimen MMRF_1912_1_PB_CD138pos (aliquot MMRF_1912_1_PB_CD138pos_T1_KBS5U_L05812) from MMRF case MMRF_1912, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.0 years (21,197 days).
Specimen MMRF_1912_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f2d1954-9649-4be1-9993-8d930b8944fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1912_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1912_1_PB_CD3pos_C4_KBS5U_L05817; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b8610fd-a199-44ed-9202-d5e9aa079e17

The open-access MAF lists 697 somatic variants for this specimen: 217 protein-altering or splice-affecting, 81 silent, 399 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 221, Missense Mutation 189, Intron 96, Silent 81, 5'UTR 40, 5'Flank 20, 3'Flank 13, Nonsense Mutation 11, RNA 9, Splice Site 6, Splice Region 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC138647.1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1449409223; called by muse, mutect2, varscan2
- ADAMTS2 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51083793; called by muse, mutect2, varscan2
- ADGRV1 | c.14852C>T p.S4951F | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1187404598; called by muse, mutect2, varscan2
- ARMC2 | c.892C>A p.H298N | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as rs1008305354; called by muse, mutect2
- ASIC2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs749146881, COSV63293686; called by muse, mutect2, varscan2
- BICD1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.112); catalogued as rs1176204686; called by muse, mutect2, varscan2
- C1orf167 | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); catalogued as rs1385146359; called by mutect2, varscan2
- C2orf91 | n.473C>G | Splice Region (SNP) | VAF 33/109 reads (30%) | catalogued as COSV101106428; called by muse, mutect2, varscan2
- CDK5RAP2 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV62572368; called by muse, mutect2, varscan2
- CGAS | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779830325; called by muse, mutect2, varscan2
- CIC | c.1505C>G p.S502C | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as rs771116358, COSV50659416; called by mutect2, varscan2
- CRYBG2 | c.4019C>T p.S1340L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57487903; called by muse, mutect2, varscan2
- CYLD | c.2042-1G>T p.X681_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as CS154513; called by muse, mutect2
- DENND1C | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV57568717; called by muse, mutect2, varscan2
- DHX29 | c.3920G>A p.R1307Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.097); catalogued as rs752824993; called by muse, mutect2, varscan2
- DOK3 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as rs748836235; called by muse, mutect2, varscan2
- DPYSL3 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs751361322, COSV58330391; called by muse, mutect2, varscan2
- EPHA8 | c.2330C>G p.S777C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1165586714; called by muse, mutect2, varscan2
- ETS1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.129); catalogued as COSV101200344; called by muse, mutect2, varscan2
- FBXO41 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV54586684; called by muse, mutect2, varscan2
- FIGN | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs576789489, COSV100291917, COSV60764866; called by muse, mutect2, varscan2
- FNDC3B | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.048); catalogued as rs993970476; called by muse, mutect2, varscan2
- FOXD2 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58304375; called by muse, mutect2
- FRMD1 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.776); catalogued as rs752860506; called by muse, mutect2, varscan2
- GALNTL5 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs368842809, COSV67180145; called by mutect2, varscan2
- GNG8 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.059); catalogued as rs532299872; called by muse, mutect2, varscan2
- GRIA2 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52390630; called by muse, mutect2, varscan2
- GSTO1 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV63846561; called by muse, mutect2, varscan2
- HEPHL1 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as rs1330956914; called by muse, mutect2
- HOMEZ | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV62537253; called by muse, mutect2, varscan2
- HOXC9 | c.165C>G p.F55L | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1407570013, COSV57716319; called by muse, mutect2
- HYDIN | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as rs372727845; called by muse, mutect2, varscan2
- INPPL1 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53354342; called by muse, mutect2, varscan2
- INTS9 | c.1056G>C p.Q352H | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755712559; called by muse, mutect2, varscan2
- IRX2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.32); catalogued as COSV57409611, COSV57413864; called by muse, mutect2, varscan2
- JPT2 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1030958285, COSV50188487, COSV99027989; called by muse, mutect2, varscan2
- KANK1 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63214044; called by muse, mutect2, varscan2
- KCNQ2 | c.2003C>T p.P668L (on ENST00000359125 / NM_172107.4; = p.P640L on NM_004518.6) | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180500980, COSV60542420; called by muse, mutect2
- KIF14 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV66264016; called by muse, mutect2, varscan2
- KIF22 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs773857563; called by muse, mutect2, varscan2
- KLC3 | c.-8-6C>T | Splice Region (SNP) | VAF 9/98 reads (9%) | catalogued as rs1276709925; called by muse, mutect2
- LIN54 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs776973799; called by muse, mutect2, varscan2
- LRRC47 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as rs760459981, COSV65562164, COSV65562861; called by muse, mutect2, varscan2
- MICALL2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1460001126; called by muse, mutect2, varscan2
- MROH7 | c.1365G>C p.K455N | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV59877847; called by mutect2, varscan2
- MRPL54 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs779084462; called by muse, mutect2, varscan2
- MYH13 | c.5117C>G p.S1706* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs760378346; called by muse, mutect2, varscan2
- NMU | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV51702616; called by muse, mutect2, varscan2
- PBX2 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV66708712; called by muse, mutect2, varscan2
- PKHD1L1 | c.5986G>C p.E1996Q | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV99058815; called by muse, mutect2, varscan2
- PTDSS2 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57278153; called by muse, mutect2, varscan2
- PTPN6 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV59684388; called by muse, varscan2
- RFWD3 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1184458444, COSV63098989; called by muse, mutect2, varscan2
- RPL8 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs777113990; called by muse, mutect2, varscan2
- SACS | c.6577G>A p.D2193N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.137); catalogued as rs149278134; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCAP | c.2515G>C p.D839H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.359); catalogued as rs1341551376; called by muse, mutect2, varscan2
- SCN9A | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.284); catalogued as COSV57606941; called by muse, mutect2, varscan2
- SEBOX | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV52647636; called by muse, mutect2, varscan2
- SETD2 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.469); catalogued as COSV57437148, COSV57449212; called by muse, mutect2, varscan2
- SGCZ | c.446A>T p.Q149L | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV66008038, COSV66034481; called by muse, mutect2
- SH3PXD2A | c.328dup p.H110Pfs*6 | Frame Shift Ins (INS) | VAF 31/96 reads (32%) | catalogued as rs777796332; called by mutect2, varscan2
- SKAP2 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV104422320; called by muse, mutect2, varscan2
- SLC25A20 | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59804496, COSV59804591; called by muse, mutect2, varscan2
- SLC2A13 | c.1368G>C p.K456N | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99786345; called by muse, mutect2, varscan2
- SP140 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs1304344903; called by mutect2, varscan2
- SPHKAP | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747553444, COSV60874023; called by mutect2, varscan2
- TCHHL1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs771462113; called by muse, varscan2
- TENM2 | c.2380G>A p.E794K (on ENST00000518659 / NM_001122679.2; = p.E562K on NM_001080428.3) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.744); catalogued as rs1259911343; called by muse, mutect2, varscan2
- TRPC4AP | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV99327965; called by muse, mutect2, varscan2
- TRPV3 | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1404147400; called by muse, mutect2, varscan2
- TTC36 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100244666; called by muse, mutect2, varscan2
- UCKL1 | c.657C>T p.L219= | Splice Region (SNP) | VAF 14/72 reads (19%) | catalogued as rs1281917749; called by muse, mutect2, varscan2
- USP49 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs548556992, COSV51897822; called by muse, mutect2, varscan2
- VWF | c.5441C>T p.A1814V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs1358922592; called by muse, mutect2
- WDR47 | c.1326G>T p.Q442H (on ENST00000369962 / NM_001142551.2; = p.Q443H on NM_014969.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100728251; called by muse, mutect2
- WDR97 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1250878822; called by muse, mutect2, varscan2
- XYLT1 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV54475980, COSV54477959; called by muse, mutect2, varscan2
- ZGRF1 | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs896620823, COSV100005802; called by muse, mutect2
- ZNF281 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs747158613; called by muse, mutect2, varscan2
- ZNF496 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.188); catalogued as rs575003355; called by muse, mutect2, varscan2
- ZNF654 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58851997; called by muse, varscan2
- ZSWIM5 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1239778288; called by muse, mutect2, varscan2
- ADCK2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- AHNAK2 | c.16210G>A p.D5404N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- AL441992.2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANGPT1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK3 | c.8704G>A p.E2902K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by mutect2, varscan2
- ARPP21 | c.687-1G>T p.X229_splice | Splice Site (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2
- ARSJ | c.1412C>G p.S471C | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by mutect2, varscan2
- ATG4B | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATL2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); called by muse, varscan2
- ATN1 | c.3262C>T p.H1088Y | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ATP6V0A1 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- B4GALT2 | c.752C>G p.A251G | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.155); called by muse, mutect2
- BBOX1 | c.917G>C p.R306T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- BPI | c.869C>T p.S290L (on ENST00000262865; = p.S286L on NM_001725.3) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- BPTF | c.8505G>C p.Q2835H | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BYSL | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CACNA1B | c.6319G>C p.E2107Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CACNA1D | c.3266C>G p.S1089C (on ENST00000350061 / NM_001128840.3; = p.S1109C on NM_000720.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CARF | c.1379G>C p.R460T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC3 | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD5 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CDKN1C | c.794A>G p.K265R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- CDKN1C | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPU | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CEP97 | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, varscan2
- CFAP44 | c.1143C>G p.I381M | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- CFAP92 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- CFP | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CHD7 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CHMP1B | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CLEC16A | c.2845C>A p.P949T | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CLUAP1 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRLF3 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CTU2 | c.819C>G p.I273M | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, varscan2
- DCAF8L2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- DHX37 | c.2835G>C p.E945D | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DNAH14 | c.2796G>C p.L932F (on ENST00000445597; = p.L998F on NM_001367479.1) | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- DST | c.11732C>T p.S3911L (on ENST00000361203 / NM_001374722.1; = p.S1499L on NM_015548.5) | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DTWD2 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EBNA1BP2 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EME2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EPB41L5 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EPG5 | c.3532C>T p.Q1178* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- FASTKD2 | c.1575C>G p.I525M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- FAT3 | c.11857G>A p.E3953K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FBN2 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FIBP | c.700G>C p.D234H (on ENST00000338369 / NM_198897.2; = p.D227H on NM_004214.5) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- FMO2 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- FREM2 | c.5642-1G>C p.X1881_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- FTL | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- GMCL1 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- GOLGA2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- GRK4 | c.1411C>T p.H471Y (on ENST00000398052 / NM_182982.3; = p.H439Y on NM_005307.3) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- HAUS5 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- HCFC2 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.186); called by muse, mutect2
- IGHV2-70D | c.337A>T p.T113S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, varscan2
- IGLV3-10 | c.47-2A>T p.X16_splice | Splice Site (SNP) | VAF 15/46 reads (33%) | called by muse, varscan2
- INTS1 | c.5566G>T p.E1856* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- IRF1 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- ITGA8 | c.66C>A p.C22* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2
- ITGAM | c.2169C>G p.I723M (on ENST00000648685 / NM_001145808.2; = p.I722M on NM_000632.4) | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- KDELR3 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.052); called by mutect2, varscan2
- KDM4A | c.2584C>T p.Q862* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | called by mutect2, varscan2
- KIAA0232 | c.437-1G>A p.X146_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | called by muse, varscan2
- LCTL | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- LINC00583 | n.171C>T | Splice Region (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- METTL3 | c.202_218del p.A68Yfs*4 | Frame Shift Del (DEL) | VAF 21/93 reads (23%) | called by mutect2, varscan2
- MMS22L | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MPDZ | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- MYO10 | c.4750G>A p.D1584N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYO16 | c.4834G>A p.E1612K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYOM3 | c.2155G>C p.G719R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- NBEAL2 | c.7189C>T p.H2397Y | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- NEDD1 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- NES | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- OPN3 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAXIP1 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIK3C2B | c.3925G>C p.E1309Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- PLCE1 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLEKHG3 | c.577G>C p.E193Q (on ENST00000394691; = p.E249Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2
- PLEKHG4 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PPARG | c.804G>C p.K268N (on ENST00000287820 / NM_015869.5; = p.K238N on NM_005037.7) | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PPFIA3 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PRKG1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRSS2 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PUS1 | c.304-4C>A | Splice Region (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- RAPGEFL1 | c.1707G>T p.K569N | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.466); called by muse, mutect2
- RCC2 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- RIC8B | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ROBO3 | c.2226C>G p.I742M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- ROS1 | c.5486G>C p.R1829T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- SACS | c.3411G>C p.K1137N | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SALL1 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2
- SALL3 | c.2562G>A p.M854I | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SCARF2 | c.2527del p.R843Gfs*101 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, varscan2
- SCN9A | c.5803G>A p.D1935N (on ENST00000303354; = p.D1924N on NM_002977.3) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SGMS1 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- SHOC1 | c.3973C>T p.Q1325* | Nonsense Mutation (SNP) | VAF 47/143 reads (33%) | called by muse, mutect2, varscan2
- SLC22A11 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLC2A11 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 31/138 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC46A3 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- SLC47A1 | c.1287dup p.A430Cfs*70 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by pindel, varscan2
- SLC8A1 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA5 | c.2878C>T p.H960Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SMG1 | c.4738G>A p.E1580K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0.017); called by muse, mutect2
- SNX17 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SOS2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SPEF2 | c.4627T>A p.S1543T | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.115); called by muse, mutect2
- SPOPL | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- SQLE | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.673); called by mutect2, varscan2
- SRGAP1 | c.1625G>C p.R542T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRPX2 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TCHHL1 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TLN1 | c.4812G>C p.K1604N | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TMED8 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TPBGL | c.1130C>A p.S377Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- TRAPPC4 | c.558C>G p.F186L | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM25 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TRPC3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC14 | c.2072C>G p.S691C | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.947); called by muse, mutect2
- TTK | c.1990G>T p.D664Y | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UMODL1 | c.2834C>T p.S945F (on ENST00000408910 / NM_001004416.2; = p.S1073F on NM_173568.3) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- UNC5B | c.16G>T p.G6* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- VWA5B2 | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.94); called by muse, varscan2
- XPA | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YWHAB | c.237G>C p.Q79H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZBTB47 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZC3H7B | c.2518-1G>C p.X840_splice | Splice Site (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- ZC3H8 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by mutect2, varscan2
- ZNF131 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF280B | c.935G>A p.C312Y | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF354B | c.1431G>C p.Q477H | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZNF571 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF747 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- ZNF773 | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKT1S1 | c.654C>T p.I218= (on ENST00000344175 / NM_001098633.4; = p.I238= on NM_032375.5) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs766848323, COSV59273976; called by muse, mutect2, varscan2
- ANKMY1 | c.348C>T p.L116= | Silent (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- ARL16 | c.411C>G p.L137= | Silent (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- ATG2B | c.5589C>T p.G1863= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs748724343; called by muse, mutect2, varscan2
- ATP1A3 | c.1737G>A p.V579= (on ENST00000545399 / NM_001256214.2; = p.V566= on NM_152296.5) | Silent (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- AUTS2 | c.2205C>T p.L735= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs1301078103; called by muse, mutect2, varscan2
- BBC3 | c.390C>T p.L130= (on ENST00000449228 / NM_001127240.3; = p.S96L on NM_014417.5) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs747413729; called by muse, mutect2, varscan2
- BHMT2 | c.129C>G p.L43= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV54873810; called by muse, mutect2
- BTBD9 | c.1554C>T p.V518= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- C12orf57 | c.180G>A p.Q60= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- CACNG6 | c.195C>T p.L65= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs769787760; called by muse, mutect2, varscan2
- CENPF | c.1143C>T p.A381= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1173255326; called by mutect2, varscan2
- CLDN3 | c.534G>A p.A178= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- CLTB | c.132C>T p.F44= | Silent (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- CNBD1 | c.471G>A p.L157= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- CYP27C1 | c.255C>T p.I85= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs146690447; called by muse, mutect2, varscan2
- DAGLB | c.1461C>T p.I487= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs758391168; called by muse, mutect2, varscan2
- DDX23 | c.1689C>T p.V563= | Silent (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- DENND5A | c.744C>G p.L248= | Silent (SNP) | VAF 44/126 reads (35%) | called by muse, mutect2, varscan2
- DNAH10 | c.8556C>A p.I2852= (on ENST00000409039; = p.I2791= on NM_207437.3) | Silent (SNP) | VAF 8/177 reads (5%) | called by muse, mutect2
- DNAH3 | c.1887G>A p.L629= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs148819655; called by muse, mutect2, varscan2
- EPG5 | c.4173G>A p.L1391= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- FBXO39 | c.483C>T p.G161= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs377688513; called by muse, mutect2, varscan2
- GLYCTK | c.1206C>T p.V402= | Silent (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- GPAT2 | c.1296C>G p.L432= | Silent (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- GRIN2B | c.1275G>A p.L425= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs950679024; ClinVar: likely benign; called by muse, mutect2
- HEXD | c.1116C>T p.V372= (on ENST00000327949 / NM_001369487.1; = p.S402L on NM_173620.3) | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV60063630; called by muse, mutect2, varscan2
- HRNR | c.228G>C p.L76= | Silent (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- HS1BP3 | c.243G>C p.L81= | Silent (SNP) | VAF 44/134 reads (33%) | called by muse, mutect2, varscan2
- IL6R | c.381C>T p.L127= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV59820004; called by muse, mutect2, varscan2
- INPP5B | c.2937G>A p.K979= (on ENST00000373023; = p.K899= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- KCNJ14 | c.30C>T p.L10= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs928639669, COSV53519720; called by muse, mutect2, varscan2
- KDSR | c.702G>A p.E234= | Silent (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- KLHL6 | c.141C>T p.V47= | Silent (SNP) | VAF 22/161 reads (14%) | catalogued as rs1004787604, COSV58069925; called by muse, varscan2
- LCT | c.5580C>T p.I1860= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- LRRC38 | c.333C>T p.L111= | Silent (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- MKRN1 | c.1005G>A p.R335= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs1062773; called by muse, mutect2, varscan2
- MUC4 | c.13353C>T p.V4451= (on ENST00000463781 / NM_018406.7; = p.V215= on NM_004532.6) | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- NAGK | c.78C>T p.I26= | Silent (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- NDST4 | c.1105C>A p.R369= | Silent (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- NDUFA7 | c.21C>G p.L7= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- NELFCD | c.1485G>A p.V495= (on ENST00000602795; = p.V477= on NM_198976.4) | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs376830862; called by muse, mutect2, varscan2
- NLGN2 | c.1695C>T p.F565= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs751321187; called by muse, mutect2, varscan2
- NOL11 | c.456G>C p.V152= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- NOX5 | c.1689C>A p.I563= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99534541; called by muse, mutect2, varscan2
- NOXRED1 | c.786G>A p.L262= | Silent (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- NSUN7 | c.1467C>T p.F489= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- PKN2 | c.510G>T p.R170= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- PLCD3 | c.903C>G p.L301= | Silent (SNP) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- PURG | c.393G>C p.L131= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV53295591, COSV53296220; called by muse, mutect2, varscan2
- RAI1 | c.5334G>C p.R1778= | Silent (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- RARS1 | c.66G>A p.L22= | Silent (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- RARS1 | c.1890G>A p.V630= | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- RETREG3 | c.225G>A p.L75= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV52220680; called by muse, varscan2
- RNF186 | c.159C>G p.P53= | Silent (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- SBF1 | c.2091C>G p.L697= | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, varscan2
- SCRT2 | c.426G>A p.A142= | Silent (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- SDF4 | c.522C>T p.I174= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV55420785, COSV99027809; called by muse, mutect2, varscan2
- SLC35F3 | c.87G>A p.R29= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs750181555, COSV64027973; called by muse, mutect2, varscan2
- SLC9A9 | c.264C>T p.F88= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV57230334; called by muse, mutect2
- SPATA2L | c.504G>A p.V168= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1339658921; called by muse, mutect2, varscan2
- SPCS2 | c.522G>C p.L174= | Silent (SNP) | VAF 33/89 reads (37%) | called by muse, mutect2, varscan2
- SPIN1 | c.732C>T p.F244= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs1424727512; called by muse, mutect2, varscan2
- SSC4D | c.861C>G p.L287= | Silent (SNP) | VAF 10/27 reads (37%) | called by mutect2, varscan2
- SYNE1 | c.21540G>A p.L7180= (on ENST00000367255 / NM_182961.4; = p.L7109= on NM_033071.3) | Silent (SNP) | VAF 32/129 reads (25%) | called by muse, mutect2, varscan2
- TBC1D9 | c.3759C>T p.L1253= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV71307368; called by muse, mutect2, varscan2
- TGFB2 | c.246G>A p.A82= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- THSD7B | c.2109C>G p.V703= | Silent (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- TMC7 | c.2046C>T p.F682= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1195732483, COSV58581655; called by muse, mutect2, varscan2
- TMED9 | c.27C>T p.L9= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs759506866; called by muse, mutect2, varscan2
- TPSB2 | c.210G>A p.L70= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs775320822; called by muse, mutect2, varscan2
- TRPC7 | c.118C>T p.L40= | Silent (SNP) | VAF 54/149 reads (36%) | called by mutect2, varscan2
- TRPV1 | c.1470C>T p.F490= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1482230799; called by muse, mutect2, varscan2
- TRRAP | c.5898G>A p.L1966= (on ENST00000359863 / NM_001244580.1; = p.L1948= on NM_003496.3) | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- UBE2Z | c.612G>A p.Q204= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100711560; called by muse, mutect2, varscan2
- USP53 | c.1266C>T p.H422= | Silent (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- VPS13A | c.3792G>A p.L1264= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1247441048, COSV62437475; called by muse, mutect2, varscan2
- VPS13C | c.7930C>T p.L2644= (on ENST00000644861 / NM_020821.3; = p.L2601= on NM_017684.5) | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as rs770094876; called by muse, mutect2
- XPR1 | c.1539G>A p.L513= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs750004423, COSV62558470; called by muse, mutect2, varscan2
- ZNF365 | c.984G>C p.S328= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV67926701; called by muse, mutect2, varscan2
- ZNF691 | c.282C>G p.V94= (on ENST00000372502; = p.V63= on NM_015911.3) | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV65289738; called by muse, mutect2, varscan2
- ABHD6 | c.119+1790C>G | Intron (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- ABLIM1 | chr10:114431406 G>A | 3'Flank (SNP) | VAF 11/56 reads (20%) | called by mutect2, varscan2
- ABRACL | c.61+286T>C | Intron (SNP) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- AC009779.3 | c.*1177C>T | 3'UTR (SNP) | VAF 12/52 reads (23%) | called by mutect2, varscan2
- AC073578.1 | n.921C>T | RNA (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- AC074085.2 | n.59G>A | RNA (SNP) | VAF 24/91 reads (26%) | catalogued as rs1239477899; called by muse, mutect2, varscan2
- ACTL10 | c.-794G>A | 5'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- ACVR1B | c.*2283C>T | 3'UTR (SNP) | VAF 9/78 reads (12%) | catalogued as rs1442233726; called by muse, mutect2, varscan2
- ADAM9 | chr8:38996951 C>T | 5'Flank (SNP) | VAF 7/25 reads (28%) | catalogued as rs1004167249; called by muse, mutect2, varscan2
- ADAM9 | c.2210+67C>T | Intron (SNP) | VAF 8/29 reads (28%) | catalogued as rs1196392530; called by mutect2, varscan2
- ADAMTS13 | c.-19C>T | 5'UTR (SNP) | VAF 17/62 reads (27%) | catalogued as rs782227169, COSV100746907; called by muse, mutect2, varscan2
- ADAR | c.2497-73C>T | Intron (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- ADCYAP1 | c.-90C>T | 5'UTR (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.*2878C>G | 3'UTR (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- ADD1 | c.1161+129G>A | Intron (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- ADD3 | c.*1684G>C | 3'UTR (SNP) | VAF 10/46 reads (22%) | called by mutect2, varscan2
- ADGRE3 | c.*106G>C | 3'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2
- ADTRP | c.*821G>A | 3'UTR (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- AGPAT2 | c.*598C>G | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- AIF1L | c.*1955G>A | 3'UTR (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- AKAP10 | c.-94C>T | 5'UTR (SNP) | VAF 10/33 reads (30%) | catalogued as rs1436252948; called by muse, mutect2, varscan2
- AL162417.1 | c.397-17010C>G | Intron (SNP) | VAF 15/49 reads (31%) | catalogued as COSV64454486; called by muse, mutect2, varscan2
- ALDH1A2 | c.*292G>A | 3'UTR (SNP) | VAF 12/94 reads (13%) | called by mutect2, varscan2
- ALDH1A3 | c.*1530G>C | 3'UTR (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- AMDHD1 | c.*419T>G | 3'UTR (SNP) | VAF 20/75 reads (27%) | catalogued as rs551075382; called by muse, varscan2
- ANK1 | c.126+67754G>A | Intron (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- ANKRD29 | c.*1950G>C | 3'UTR (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- AP3S2 | chr15:89894333 C>T | 5'Flank (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- APPL2 | chr12:105236350 G>A | 5'Flank (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.-334G>A | 5'UTR (SNP) | VAF 13/43 reads (30%) | catalogued as rs1466535811; called by muse, mutect2, varscan2
- ARHGAP5 | c.*3952C>G | 3'UTR (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- ARID2 | chr12:45727455 G>A | 5'Flank (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- ARSJ | c.*1819G>A | 3'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- ASCC1 | c.*531C>G | 3'UTR (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- ASCC3 | c.241+6224G>C | Intron (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- ATF5 | c.*86C>T | 3'UTR (SNP) | VAF 4/12 reads (33%) | catalogued as rs757195194; called by muse, varscan2
- ATL2 | c.603+85C>T | Intron (SNP) | VAF 3/49 reads (6%) | catalogued as rs1357147886; called by muse, mutect2
- BACE1 | c.*3738G>T | 3'UTR (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- BAIAP2 | c.280-115C>T | Intron (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- BARX1 | c.*379C>T | 3'UTR (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- BBC3 | c.378-253C>T | Intron (SNP) | VAF 13/53 reads (25%) | called by mutect2, varscan2
- BDNF | c.*2187G>C | 3'UTR (SNP) | VAF 36/111 reads (32%) | catalogued as rs552619701; called by muse, mutect2, varscan2
- BIRC6 | c.*851G>A | 3'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- BLM | c.*223C>T | 3'UTR (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- BMP6 | c.*323C>T | 3'UTR (SNP) | VAF 21/79 reads (27%) | called by muse, varscan2
- BMP6 | c.*364C>T | 3'UTR (SNP) | VAF 26/92 reads (28%) | called by muse, varscan2
- BMP6 | c.*1187G>A | 3'UTR (SNP) | VAF 32/96 reads (33%) | catalogued as rs200877924; called by muse, varscan2
- BRWD1 | c.6572-2980C>A | Intron (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- BTK | c.*247G>T | 3'UTR (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100437816; called by muse, mutect2, varscan2
- BX119917.1 | n.9C>T | RNA (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- C10orf53 | c.*985G>C | 3'UTR (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2
- C11orf80 | c.1043-80C>T | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- C1R | c.1080+965G>A | Intron (SNP) | VAF 14/50 reads (28%) | catalogued as rs1018684479; called by muse, mutect2, varscan2
- C2orf16 | c.*73C>T | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- CACNA1D | c.4111-42G>A | Intron (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- CACUL1 | c.*1295C>T | 3'UTR (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- CADM1 | c.*6859C>G | 3'UTR (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- CALHM1 | c.*394C>G | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by mutect2, varscan2
- CAMTA2 | c.3262-9C>T | Intron (SNP) | VAF 12/56 reads (21%) | called by mutect2, varscan2
- CASC3 | chr17:40140508 G>A | 5'Flank (SNP) | VAF 8/63 reads (13%) | catalogued as rs762844864, COSV99229878; called by muse, mutect2, varscan2
- CCDC117 | c.-35G>A | 5'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as rs959401370; called by mutect2, varscan2
- CCDC138 | c.-41G>A | 5'UTR (SNP) | VAF 15/47 reads (32%) | catalogued as rs1369738676; called by muse, mutect2, varscan2
- CCDC71L | c.*1559C>T | 3'UTR (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- CCDC73 | c.429+126C>G | Intron (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- CD164 | c.-61G>A | 5'UTR (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- CD46 | c.1027+70G>A | Intron (SNP) | VAF 14/52 reads (27%) | catalogued as rs1308442813; called by muse, mutect2
- CDK13 | c.1211+81C>T | Intron (SNP) | VAF 14/50 reads (28%) | catalogued as rs1248230192; called by muse, mutect2
- CDKL4 | chr2:39175881 G>A | 3'Flank (SNP) | VAF 6/63 reads (10%) | catalogued as rs561661705; called by muse, mutect2
- CDKN2B | c.*1244G>A | 3'UTR (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- CDS2 | c.*3026C>T | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- CDX1 | c.*260C>G | 3'UTR (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- CEBPB | c.*320G>A | 3'UTR (SNP) | VAF 21/81 reads (26%) | catalogued as COSV100269827; called by muse, mutect2, varscan2
- CEP250 | c.948+142G>T | Intron (SNP) | VAF 6/123 reads (5%) | called by muse, mutect2
- CEP78 | c.*4402G>C | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2
- CERK | c.*2370C>T | 3'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- CFL2 | c.3+23G>A | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- CHFR | chr12:132840283 C>T | 3'Flank (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- CHRNA5 | c.*1520T>C | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- CHRNB1 | c.-26G>A | 5'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- CHST3 | c.*3344T>C | 3'UTR (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- CLASP2 | c.862+237C>T | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2
- CLEC4G | c.221-35G>A | Intron (SNP) | VAF 13/38 reads (34%) | catalogued as rs1223841681; called by muse, mutect2, varscan2
- CLRN1 | chr3:150926373 C>T | 3'Flank (SNP) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- COBLL1 | c.64+25G>A | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, varscan2
- COMT | c.615+1239C>T | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- COPS8 | c.*1966G>A | 3'UTR (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- CRCT1 | c.-4C>T | 5'UTR (SNP) | VAF 22/146 reads (15%) | catalogued as COSV57500179; called by muse, mutect2, varscan2
- CRYBA2 | c.303+78C>G | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- CSMD1 | c.-298C>T | 5'UTR (SNP) | VAF 4/10 reads (40%) | catalogued as COSV68207843; called by muse, mutect2
- CTCF | c.*1073C>A | 3'UTR (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- CTDSP1 | c.-213C>G | 5'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- CTNND2 | c.*1477G>C | 3'UTR (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- CTSD | c.*437C>G | 3'UTR (SNP) | VAF 30/106 reads (28%) | catalogued as rs698450; called by muse, mutect2, varscan2
- CTSS | c.*1119C>T | 3'UTR (SNP) | VAF 13/57 reads (23%) | called by mutect2, varscan2
- CUL7 | c.-36C>T | 5'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2
- CXCR3 | c.*271C>T | 3'UTR (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- DCHS2 | n.1502C>G | RNA (SNP) | VAF 12/86 reads (14%) | called by mutect2, varscan2
- DCT | c.*1436C>G | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- DDX27 | c.1367-154C>G | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- DDX39B | c.-3+142C>T | Intron (SNP) | VAF 20/85 reads (24%) | catalogued as rs931986231; called by muse, mutect2, varscan2
- DEPDC5 | c.1666+490C>T | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- DHDDS | c.*1957C>T | 3'UTR (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- DIS3L | c.2201+23G>A | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- DRAM1 | c.*1878C>T | 3'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- DTX2P1 | n.303C>G | RNA (SNP) | VAF 28/97 reads (29%) | catalogued as rs1372146214; called by muse, mutect2, varscan2
- DUSP5 | c.*857C>T | 3'UTR (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- DVL2 | c.1034+46C>A | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- ECT2L | c.*447G>A | 3'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- EED | c.-414G>A | 5'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- EFCAB2 | c.*2349C>T | 3'UTR (SNP) | VAF 13/104 reads (13%) | catalogued as rs1252269326; called by muse, mutect2, varscan2
- ELK4 | c.1081-219G>A | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- ELOVL6 | c.*1590G>C | 3'UTR (SNP) | VAF 21/62 reads (34%) | called by muse, varscan2
- ENPEP | c.*958C>T | 3'UTR (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- ENTPD5 | c.*438G>A | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- EPAS1 | c.*1308G>C | 3'UTR (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- EPHA10 | c.*2229C>G | 3'UTR (SNP) | VAF 40/121 reads (33%) | called by muse, mutect2, varscan2
- ERCC6 | c.*693C>T | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- ERCC6 | c.1397+7681G>T | Intron (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- EVL | c.1089-137G>A | Intron (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2
- FAM114A1 | c.*140G>A | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- FAM114A1 | c.*340G>C | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- FAM118A | c.522+392C>T | Intron (SNP) | VAF 7/37 reads (19%) | catalogued as rs757119767; called by muse, mutect2, varscan2
- FAM133B | c.-91G>A | 5'UTR (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- FAM151B | chr5:80487996 C>T | 5'Flank (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- FAM161A | c.*620G>A | 3'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- FAM193B | c.210+697C>A | Intron (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2
- FAM219A | c.*1613G>C | 3'UTR (SNP) | VAF 15/153 reads (10%) | called by mutect2, varscan2
- FAM98B | c.*315C>G | 3'UTR (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- FBXW7 | c.502-2690G>A | Intron (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- FBXW8 | chr12:117029996 G>T | 3'Flank (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- FCRL1 | c.*1203C>G | 3'UTR (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- FER | c.1924+4137G>T | Intron (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- FOXC1 | c.*669G>C | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- FOXC1 | c.*957C>A | 3'UTR (SNP) | VAF 8/59 reads (14%) | catalogued as rs1029465164; called by muse, mutect2, varscan2
- FRMD3 | c.*1546G>C | 3'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- FUT2 | chr19:48705684 C>G | 3'Flank (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- GABRB2 | c.*1949G>A | 3'UTR (SNP) | VAF 20/72 reads (28%) | catalogued as rs1311280506; called by muse, mutect2, varscan2
- GARRE1 | c.-128C>T | 5'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- GDF15 | c.277+97C>G | Intron (SNP) | VAF 41/143 reads (29%) | called by mutect2, varscan2
- GIGYF1 | c.*87G>C | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- GLIPR1 | c.*3529C>T | 3'UTR (SNP) | VAF 17/129 reads (13%) | called by muse, mutect2, varscan2
- GOLGA4 | chr3:37243087 G>A | 5'Flank (SNP) | VAF 11/33 reads (33%) | catalogued as rs1275939269; called by muse, mutect2, varscan2
- GREM2 | c.*1414C>A | 3'UTR (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- GRIK3 | c.*4766G>A | 3'UTR (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- GRIN2A | c.*5009G>A | 3'UTR (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- GRIN2C | chr17:74860533 G>A | 5'Flank (SNP) | VAF 11/40 reads (28%) | catalogued as rs775539387; called by muse, mutect2, varscan2
- GRM3 | c.*5G>A | 3'UTR (SNP) | VAF 16/228 reads (7%) | catalogued as COSV100862838; called by muse, mutect2
- GTF2H5 | c.*1538G>C | 3'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- GXYLT1 | c.*1578G>A | 3'UTR (SNP) | VAF 17/49 reads (35%) | catalogued as COSV55142283; called by muse, mutect2, varscan2
- HADHA | c.*213G>C | 3'UTR (SNP) | VAF 12/36 reads (33%) | called by mutect2, varscan2
- HAND1 | c.*421C>G | 3'UTR (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- HCN1 | c.*1882C>G | 3'UTR (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- HFE | c.*3298G>C | 3'UTR (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- HFE | c.*3702C>G | 3'UTR (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- HLA-DQB1 | c.*227G>A | 3'UTR (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- HOXB3 | chr17:48549787 C>T | 3'Flank (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- HYAL2 | c.-46-526G>A | Intron (SNP) | VAF 30/113 reads (27%) | catalogued as rs940145974; called by muse, mutect2, varscan2
- ICA1L | c.235+23C>G | Intron (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2
- ID1 | c.*86C>T | 3'UTR (SNP) | VAF 16/38 reads (42%) | catalogued as rs1012250246; called by muse, mutect2, varscan2
- ID2 | c.-100G>A | 5'UTR (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99301046, COSV99301128; called by muse, mutect2, varscan2
- IFFO1 | c.1350+42C>T | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as rs1164118862; called by muse, mutect2, varscan2
- IGSF11 | c.*1536C>T | 3'UTR (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- IL6ST | c.*4920C>G | 3'UTR (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- INSYN2A | c.*1731C>A | 3'UTR (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- ITGA3 | c.*1023C>T | 3'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- KAT5 | c.592-62G>A | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- KATNAL2 | c.1211+6930C>T | Intron (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- KCNMB4 | c.*3432G>A | 3'UTR (SNP) | VAF 17/129 reads (13%) | called by muse, mutect2, varscan2
- KCNN3 | c.*443C>G | 3'UTR (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- KCNV1 | chr8:109974984 C>T | 5'Flank (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- KIAA1549 | c.*5263G>A | 3'UTR (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- KIAA1549L | c.*2635C>T | 3'UTR (SNP) | VAF 42/115 reads (37%) | called by muse, mutect2
- KIAA2012 | c.1474+29C>G | Intron (SNP) | VAF 31/96 reads (32%) | catalogued as rs1016056886; called by muse, mutect2, varscan2
- KIF20A | c.*60G>T | 3'UTR (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- KIF26B | c.*87C>T | 3'UTR (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100831820; called by muse, mutect2
- KLC4 | c.-26+665G>T | Intron (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2
- KLF9 | c.-1100C>T | 5'UTR (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- KLHDC10 | c.*200C>G | 3'UTR (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- KLHL22 | c.-33-539C>G | Intron (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- KPNA6 | c.*5333C>G | 3'UTR (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- KRAS | c.*2351C>G | 3'UTR (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- KRT14 | c.*110C>T | 3'UTR (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- KRT15 | chr17:41519878 G>A | 5'Flank (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- KRT73 | c.*243C>G | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- KRTAP17-1 | c.*293G>T | 3'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- LARP1 | c.*465C>T | 3'UTR (SNP) | VAF 27/132 reads (20%) | catalogued as rs1177961859; called by muse, mutect2, varscan2
- LARP6 | c.200+2004G>A | Intron (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- LDAH | c.*436G>C | 3'UTR (SNP) | VAF 4/27 reads (15%) | catalogued as rs1469207686; called by muse, mutect2
- LIPI | c.*66C>T | 3'UTR (SNP) | VAF 52/139 reads (37%) | called by muse, mutect2, varscan2
- LMO1 | chr11:8268695 C>T | 5'Flank (SNP) | VAF 14/30 reads (47%) | catalogued as rs1031308629; called by muse, mutect2, varscan2
- LPCAT4 | c.1242+37G>C | Intron (SNP) | VAF 3/43 reads (7%) | catalogued as COSV59215860; called by muse, mutect2
- LRATD2 | c.*3237G>A | 3'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- LRCH4 | c.*982G>A | 3'UTR (SNP) | VAF 17/82 reads (21%) | catalogued as rs928081279; called by muse, mutect2, varscan2
- LRRC28 | c.*754G>C | 3'UTR (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1551+376G>A | Intron (SNP) | VAF 30/96 reads (31%) | called by muse, varscan2
- MALT1 | c.*3130C>T | 3'UTR (SNP) | VAF 17/62 reads (27%) | catalogued as rs1450119255; called by muse, mutect2, varscan2
- MAN1B1 | c.*406G>C | 3'UTR (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2
- MAPK10 | c.311+134C>T | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- MAPK12 | c.426+43C>A | Intron (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- MARCHF6 | c.*1369G>C | 3'UTR (SNP) | VAF 13/66 reads (20%) | called by mutect2, varscan2
- MARK2 | c.-414G>A | 5'UTR (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- MAST4 | c.674+17119C>G | Intron (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- MBLAC2 | c.*1039C>A | 3'UTR (SNP) | VAF 24/84 reads (29%) | called by muse, varscan2
- MC4R | c.*112G>C | 3'UTR (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- MCC | c.-536G>A | 5'UTR (SNP) | VAF 23/73 reads (32%) | catalogued as rs893824697; called by muse, mutect2, varscan2
- MCMDC2 | c.*855G>T | 3'UTR (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- MDM1 | c.*678G>A | 3'UTR (SNP) | VAF 7/26 reads (27%) | catalogued as rs936530539; called by muse, mutect2, varscan2
- MECP2 | c.*8104G>C | 3'UTR (SNP) | VAF 38/58 reads (66%) | called by muse, mutect2, varscan2
- MEMO1 | c.62-19792G>A | Intron (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- MFAP5 | c.*226C>T | 3'UTR (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- MIA2 | c.*800G>A | 3'UTR (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- MIR365B | n.28G>A | RNA (SNP) | VAF 37/180 reads (21%) | catalogued as rs753933844; called by muse, mutect2, varscan2
- MIR600 | chr9:123111654 G>A | 5'Flank (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- MOB4 | chr2:197515622 C>T | 5'Flank (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- MOGS | c.352+63G>C | Intron (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- MRPL50 | c.*1097C>T | 3'UTR (SNP) | VAF 59/193 reads (31%) | called by muse, mutect2, varscan2
- MRPS35 | chr12:27710733 C>G | 5'Flank (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- MRS2 | c.*1299G>A | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- MST1L | n.112G>C | RNA (SNP) | VAF 9/150 reads (6%) | catalogued as rs778106909; called by muse, mutect2
- MTHFR | c.*617C>G | 3'UTR (SNP) | VAF 14/61 reads (23%) | called by mutect2, varscan2
- MTHFSD | c.681+51C>T | Intron (SNP) | VAF 12/43 reads (28%) | called by mutect2, varscan2
- MYH16 | n.4025G>A | RNA (SNP) | VAF 15/48 reads (31%) | catalogued as rs999891692; called by muse, mutect2, varscan2
- MYL1 | c.-26T>C | 5'UTR (SNP) | VAF 35/114 reads (31%) | called by muse, mutect2, varscan2
- N4BP2 | c.*330G>A | 3'UTR (SNP) | VAF 5/64 reads (8%) | catalogued as rs1171345169; called by muse, mutect2
- NAA40 | c.*2077C>T | 3'UTR (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- NAA40 | c.*2563G>A | 3'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as rs940554452; called by muse, mutect2
- NAGK | chr2:71068473 G>A | 5'Flank (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- NAP1L5 | c.-24G>C | 5'UTR (SNP) | VAF 17/67 reads (25%) | catalogued as rs371680899; called by muse, mutect2, varscan2
- NAPA | c.667-48G>A | Intron (SNP) | VAF 17/58 reads (29%) | catalogued as rs1183664654; called by muse, mutect2, varscan2
- NDST1 | c.*3736G>A | 3'UTR (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- NDUFA5 | c.*3533G>T | 3'UTR (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- NDUFS3 | c.381+109G>A | Intron (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- NEDD4L | c.49-16445G>A | Intron (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- NEK4 | c.*1028C>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2
- NF1 | c.7870-9T>G | Intron (SNP) | VAF 30/101 reads (30%) | called by muse, mutect2, varscan2
- NFASC | c.*4095G>A | 3'UTR (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- NHLH2 | c.*634G>A | 3'UTR (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- NME4 | c.*168C>T | 3'UTR (SNP) | VAF 31/102 reads (30%) | catalogued as COSV99556801; called by muse, mutect2, varscan2
- NODAL | c.*254G>A | 3'UTR (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- NPR3 | c.*2916C>T | 3'UTR (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99423713; called by muse, mutect2, varscan2
- NRBP2 | c.*1296C>T | 3'UTR (SNP) | VAF 16/58 reads (28%) | catalogued as rs966022251; called by muse, mutect2, varscan2
- NRM | c.*249C>T | 3'UTR (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- NSUN3 | c.*1098G>T | 3'UTR (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- NUDT21 | c.*1824C>T | 3'UTR (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- NUDT21 | c.*573C>T | 3'UTR (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- NUP155 | c.3931-48C>G | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- NXPH3 | c.*3114C>T | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- OR51E2 | c.*231G>C | 3'UTR (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- OSBPL9 | c.1909-77C>T | Intron (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2
- PACSIN2 | c.*793C>A | 3'UTR (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- PANK3 | c.*5434A>C | 3'UTR (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- PCDH7 | c.-874G>A | 5'UTR (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- PCDH7 | c.-555G>A | 5'UTR (SNP) | VAF 32/99 reads (32%) | called by muse, varscan2
- PCDHB11 | c.*125C>G | 3'UTR (SNP) | VAF 4/17 reads (24%) | catalogued as rs1306876868; called by muse, mutect2
- PCMTD1 | c.*2007T>G | 3'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- PDIA3 | c.167+162G>A | Intron (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- PDLIM4 | c.670+85C>T | Intron (SNP) | VAF 36/97 reads (37%) | catalogued as rs1017431672, COSV53804263; called by muse, mutect2, varscan2
- PFKFB2 | c.*252C>G | 3'UTR (SNP) | VAF 18/77 reads (23%) | catalogued as rs984961081; called by muse, mutect2, varscan2
- PGM3 | c.*413G>A | 3'UTR (SNP) | VAF 12/50 reads (24%) | called by mutect2, varscan2
- PGM3 | c.*78G>C | 3'UTR (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- PHF14 | c.*311G>A | 3'UTR (SNP) | VAF 10/38 reads (26%) | called by mutect2, varscan2
- PHLDA3 | c.-153G>T | 5'UTR (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- PIGP | c.*134G>C | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- PKP3 | c.1449-95C>T | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs1392877331; called by muse, mutect2
- PLA2G5 | c.*456C>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- PLEKHA7 | c.2008-43C>G | Intron (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- PLPP4 | c.*235G>A | 3'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- PLPP6 | c.*1007C>T | 3'UTR (SNP) | VAF 13/72 reads (18%) | called by mutect2, varscan2
- PLXNB1 | c.*412C>T | 3'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- PPIG | c.*925C>T | 3'UTR (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- PPP2CA | c.*1121C>G | 3'UTR (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- PRTG | c.*4858G>A | 3'UTR (SNP) | VAF 19/59 reads (32%) | catalogued as rs1054805717; called by muse, mutect2, varscan2
- PRUNE1 | c.*1198C>G | 3'UTR (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- PRUNE2 | c.*265C>G | 3'UTR (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- PTGS1 | c.*507G>C | 3'UTR (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- PUS1 | c.-383C>T | 5'UTR (SNP) | VAF 19/43 reads (44%) | called by muse, varscan2
- RARA | c.179-5510C>T | Intron (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- RASSF6 | c.*987C>G | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- RASSF6 | c.*572C>T | 3'UTR (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- RAX | c.*1097G>A | 3'UTR (SNP) | VAF 36/130 reads (28%) | called by muse, mutect2, varscan2
- RBBP4 | c.16+196G>A | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as rs996740113, COSV59385556; called by muse, mutect2
- RCOR3 | c.*745G>A | 3'UTR (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- RCSD1 | c.*1055C>G | 3'UTR (SNP) | VAF 10/42 reads (24%) | called by mutect2, varscan2
- RGMA | c.15-761G>A | Intron (SNP) | VAF 16/103 reads (16%) | called by muse, varscan2
- RGPD1 | chr2:86903878 C>T | 5'Flank (SNP) | VAF 17/50 reads (34%) | catalogued as rs775668723; called by muse, mutect2, varscan2
- RHOT2 | c.*559C>T | 3'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- RHPN1 | c.*943C>G | 3'UTR (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- ROBO4 | c.2435+60C>T | Intron (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- RPS17 | c.*481C>G | 3'UTR (SNP) | VAF 17/319 reads (5%) | catalogued as rs1042103635; called by muse, mutect2
- RPS3 | chr11:75405121 C>T | 3'Flank (SNP) | VAF 6/22 reads (27%) | catalogued as rs912132655; called by muse, mutect2
- RRAGD | c.-251G>A | 5'UTR (SNP) | VAF 24/71 reads (34%) | catalogued as rs1314657270; called by muse, mutect2, varscan2
- RTF2 | c.*551G>A | 3'UTR (SNP) | VAF 4/42 reads (10%) | catalogued as rs1025856694; called by muse, mutect2
- RXRB | c.1349-70C>T | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- SAMD5 | c.*1997G>A | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- SART3 | c.*412G>A | 3'UTR (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- SAV1 | chr14:50632429 C>T | 3'Flank (SNP) | VAF 28/72 reads (39%) | catalogued as rs1011888583; called by muse, mutect2, varscan2
- SCART1 | c.*161C>G | 3'UTR (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- SCRN2 | c.1-48C>T | Intron (SNP) | VAF 8/33 reads (24%) | catalogued as rs1302118976; called by mutect2, varscan2
- SEC61A1 | c.-38G>C | 5'UTR (SNP) | VAF 14/43 reads (33%) | catalogued as rs1456002740; called by muse, mutect2, varscan2
- SECISBP2L | c.*1091G>A | 3'UTR (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- SECISBP2L | c.-63G>A | 5'UTR (SNP) | VAF 22/69 reads (32%) | catalogued as rs1027196542; called by muse, mutect2, varscan2
- SELENOI | chr2:26346108 G>A | 5'Flank (SNP) | VAF 27/68 reads (40%) | catalogued as rs376678544; called by muse, mutect2, varscan2
- SELL | c.*310C>T | 3'UTR (SNP) | VAF 31/131 reads (24%) | called by muse, varscan2
- SEMA4A | c.*510C>T | 3'UTR (SNP) | VAF 9/136 reads (7%) | catalogued as rs946902747; called by muse, mutect2
- SEPTIN14 | c.*1347G>T | 3'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- SH3BP5 | c.-20C>T | 5'UTR (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2
- SHISA9 | c.-19G>C | 5'UTR (SNP) | VAF 6/15 reads (40%) | catalogued as rs964671969; called by muse, mutect2, varscan2
- SHMT1 | c.*68G>A | 3'UTR (SNP) | VAF 10/44 reads (23%) | called by mutect2, varscan2
- SIGLEC6 | c.*493C>T | 3'UTR (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- SIK2 | c.*5223C>G | 3'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- SIRPB2 | c.860-470C>G | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- SIX4 | c.*3617G>A | 3'UTR (SNP) | VAF 18/74 reads (24%) | called by mutect2, varscan2
- SIX4 | c.*1539G>C | 3'UTR (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- SKIL | c.*426G>A | 3'UTR (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- SLC22A13 | c.*951G>A | 3'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- SLC22A16 | c.53+147C>T | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- SLC2A13 | c.1034+308G>A | Intron (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- SLC37A4 | c.984+111C>T | Intron (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2
- SLC4A8 | c.1248+186C>T | Intron (SNP) | VAF 16/52 reads (31%) | catalogued as rs1402511191; called by muse, mutect2, varscan2
- SLIT3 | c.1459+9G>A | Intron (SNP) | VAF 14/55 reads (25%) | catalogued as rs1265231718; called by muse, mutect2, varscan2
- SMAD3 | c.1010-31C>T | Intron (SNP) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- SMC4 | chr3:160399837 G>A | 5'Flank (SNP) | VAF 35/105 reads (33%) | catalogued as rs868759380; called by muse, mutect2, varscan2
- SMOC2 | c.*480G>A | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- SOX11 | c.*3833G>A | 3'UTR (SNP) | VAF 21/73 reads (29%) | called by muse, varscan2
- SOX21 | c.*767G>A | 3'UTR (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- SOX3 | c.*455G>C | 3'UTR (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- SP1 | c.*4055C>G | 3'UTR (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- SPICE1 | c.*2003C>G | 3'UTR (SNP) | VAF 14/47 reads (30%) | catalogued as rs990697119; called by mutect2, varscan2
- SPN | c.*4300C>T | 3'UTR (SNP) | VAF 10/33 reads (30%) | catalogued as rs1219553310; called by muse, mutect2, varscan2
- SPRED1 | c.*3151C>G | 3'UTR (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- SRPK1 | c.*1272G>C | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- SRPX | c.-36G>A | 5'UTR (SNP) | VAF 13/53 reads (25%) | catalogued as rs1279449199; called by muse, mutect2, varscan2
- SRSF5 | c.-82C>T | 5'UTR (SNP) | VAF 14/30 reads (47%) | catalogued as rs764363876, COSV67937067; called by muse, mutect2, varscan2
- SSPOP | n.3957G>A | RNA (SNP) | VAF 25/52 reads (48%) | catalogued as rs372778854; called by muse, mutect2, varscan2
- ST6GAL1 | c.*871G>A | 3'UTR (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- ST6GAL1 | c.*1939G>A | 3'UTR (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- STAB1 | c.4761+29C>G | Intron (SNP) | VAF 11/41 reads (27%) | called by mutect2, varscan2
- STIM1 | c.1474+1243G>C | Intron (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- STON1 | c.*1306C>T | 3'UTR (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- SUSD6 | c.*2595G>A | 3'UTR (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- SYS1 | c.*1201C>T | 3'UTR (SNP) | VAF 18/80 reads (23%) | catalogued as rs915187214; called by muse, mutect2, varscan2
- SYT10 | c.*1089G>A | 3'UTR (SNP) | VAF 14/39 reads (36%) | catalogued as rs1356490360; called by muse, mutect2, varscan2
- TACC1 | c.162-143C>T | Intron (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- TACC3 | c.2062+99G>A | Intron (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2
- TBC1D5 | c.*1691G>C | 3'UTR (SNP) | VAF 7/36 reads (19%) | called by mutect2, varscan2
- TBC1D9B | c.*1162C>T | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- TCAIM | c.*474C>T | 3'UTR (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- TCTN3 | c.*570C>G | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- THADA | c.2312-1848G>C | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- THY1 | c.37+175G>A | Intron (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2
- TIGIT | c.*1102C>T | 3'UTR (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- TLE3 | c.373-709G>A | Intron (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- TMBIM4 | c.97+726G>A | Intron (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- TMC3 | c.*1005C>T | 3'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- TMEM14A | c.*225C>T | 3'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- TMEM154 | c.-13G>A | 5'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- TOR1AIP1 | chr1:179882271 G>A | 5'Flank (SNP) | VAF 20/214 reads (9%) | called by muse, varscan2
- TP63 | c.*785G>A | 3'UTR (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- TRIM24 | c.364+169C>G | Intron (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- TRIM67 | c.*1525G>A | 3'UTR (SNP) | VAF 37/166 reads (22%) | called by muse, mutect2, varscan2
- TRPV5 | c.*338G>A | 3'UTR (SNP) | VAF 11/80 reads (14%) | catalogued as rs1296679950; called by mutect2, varscan2
- TSGA13 | c.*188G>A | 3'UTR (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- TTBK1 | c.*140G>A | 3'UTR (SNP) | VAF 7/26 reads (27%) | catalogued as rs1345421117; called by muse, varscan2
- TUBA1B | c.4-406G>A | Intron (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- UBE2K | c.-154G>A | 5'UTR (SNP) | VAF 23/75 reads (31%) | catalogued as rs536698416; called by muse, mutect2, varscan2
- UBE3B | c.3016-491C>G | Intron (SNP) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- UBE4A | chr11:118401287 G>A | 3'Flank (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- UNC5D | c.*3961G>A | 3'UTR (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- UQCRB | c.*4082G>C | 3'UTR (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- VPS33A | c.*1025G>C | 3'UTR (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- VPS36 | c.*1770C>T | 3'UTR (SNP) | VAF 16/27 reads (59%) | catalogued as rs1005683104; called by muse, mutect2, varscan2
- VPS51 | c.*54C>T | 3'UTR (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99659896; called by muse, mutect2, varscan2
- VPS72 | c.271-55C>G | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- VWA5A | chr11:124147658 A>C | 3'Flank (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- WDR91 | c.1491-78G>A | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- WFDC5 | c.*260C>G | 3'UTR (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- WIPI2 | c.-99G>A | 5'UTR (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- WNT9A | c.*1139C>G | 3'UTR (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- WWC2 | c.*888G>A | 3'UTR (SNP) | VAF 15/49 reads (31%) | catalogued as rs1292117130; called by muse, mutect2, varscan2
- WWP2 | c.*59G>C | 3'UTR (SNP) | VAF 24/79 reads (30%) | catalogued as COSV100598375; called by muse, mutect2, varscan2
- XPO4 | c.*1887C>T | 3'UTR (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- YIPF6 | c.*817G>T | 3'UTR (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- ZBTB38 | chr3:141447318 C>T | 3'Flank (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- ZCWPW1 | c.361+93C>T | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2
- ZCWPW1 | c.361+91C>T | Intron (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2
- ZEB2 | c.-119G>A | 5'UTR (SNP) | VAF 10/38 reads (26%) | catalogued as rs975939990; called by mutect2, varscan2
- ZFAT | c.2475+94C>T | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2
- ZFP2 | c.*411G>T | 3'UTR (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- ZIC2 | c.1076-60G>C | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- ZNF207 | chr17:32371505 C>G | 3'Flank (SNP) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- ZNF252P | chr8:145004185 G>C | 5'Flank (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- ZNF326 | c.*743G>A | 3'UTR (SNP) | VAF 21/80 reads (26%) | catalogued as rs994022538; called by muse, mutect2, varscan2
- ZNF469 | c.*130G>C | 3'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs983965354; called by muse, mutect2, varscan2
- ZNF584 | c.*32G>A | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- ZNF594 | c.*1772C>G | 3'UTR (SNP) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- ZNF615 | c.-255G>A | 5'UTR (SNP) | VAF 34/128 reads (27%) | catalogued as rs1368523263; called by muse, varscan2
- ZNF619 | c.-149C>T | 5'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- ZNF704 | c.*10760G>C | 3'UTR (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- ZNF823 | c.-116G>A | 5'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
